Surgical pathology report (de-identified scan), TCGA case TCGA-22-5478, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-5478-01A (Primary Tumor).

TCGA-22-5478

DIAGNOSIS:

Lung, right lower lobe, lobectomy: Grade 3 (of 4) squamous cell carcinoma forms a 3.8 x 3.7 x 3.5 cm mass that invades through the visceral pleura. Multiple (8) intrapulmonary peribronchial lymph nodes are negative for tumor. The bronchial margin is negative for tumor.

Lymph nodes, superior and inferior mediastinal, excision: Multiple superior mediastinal (3 right paratracheal) and inferior mediastinal (4 subcarinal) lymph nodes are negative for tumor.

Source: NCI Genomic Data Commons file 364833a1-d0dd-4dda-b97b-dd357f679970 (TCGA-22-5478.912BF8BA-D6BB-4643-A5DD-3449C86CEEC3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).